Somatic mutation profile of tumor specimen MP2PRT-PASGTJ-TBP1-A (aliquot MP2PRT-PASGTJ-TBP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASGTJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,092 days).
Specimen MP2PRT-PASGTJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa83608c-5601-47f6-bd4d-fa34cc4e4aa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASGTJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASGTJ-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c38eb92-a9ab-4818-bf66-d54422236ade

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP76 | c.962G>A p.C321Y | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs770831877; called by muse, mutect2, varscan2
- LYPD6 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs1483933287, COSV61940055, COSV61941991; called by muse, mutect2
- MGAT4C | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 11/350 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.342); catalogued as rs1428416204, COSV100152770; called by muse, mutect2
- PROC | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 29/403 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766261022, CM128573, CM930620, CM951020, COSV52167814; ClinVar: uncertain significance; called by muse, mutect2
- SCN5A | c.5134G>A p.G1712S (on ENST00000333535 / NM_198056.3; = p.G1711S on NM_000335.5) | Missense Mutation (SNP) | VAF 53/331 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473298, CM100755; ClinVar: not provided; called by muse, mutect2, varscan2
- SEMA5A | c.2020C>G p.Q674E | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV66806165; called by muse, mutect2
- SMARCA2 | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61805624; called by muse, mutect2
- ZPLD1 | c.67G>A p.G23S (on ENST00000466937 / NM_001329788.1; = p.G39S on NM_175056.2) | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs747508648, COSV60355686; called by muse, mutect2, varscan2
- ALG10 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 31/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- MYH2 | c.2517C>G p.F839L | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TIAM2 | c.3460C>T p.Q1154* | Nonsense Mutation (SNP) | VAF 12/314 reads (4%) | called by muse, mutect2
- FIGNL2 | c.1431C>T p.F477= | Silent (SNP) | VAF 29/444 reads (7%) | called by muse, mutect2
- GLB1L2 | c.1731C>T p.F577= | Silent (SNP) | VAF 15/301 reads (5%) | called by muse, mutect2
- OTOGL | c.5970C>T p.F1990= (on ENST00000547103; = p.F1981= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 16/341 reads (5%) | catalogued as COSV54016988; called by muse, mutect2
- TGIF1 | c.669C>T p.L223= (on ENST00000330513 / NM_001374396.1; = p.L243= on NM_003244.4) | Silent (SNP) | VAF 31/440 reads (7%) | catalogued as COSV57907123; called by muse, mutect2
